Gene-level copy-number profile of tumor specimen TCGA-75-7031-01A from TCGA case TCGA-75-7031, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-7031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.dbd564cf-3e03-4fbb-8261-5abc653a53ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-7031-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f835e91-d12f-49c8-82c4-05bab4b888be

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 388; copy number 2: 8,028; copy number 3: 17,131; copy number 4: 18,447; copy number 5: 8,704; copy number 6: 3,477; copy number 7: 647; copy number 8: 369; copy number 9: 820; copy number 10: 30; copy number 11: 159; copy number 12: 381; copy number 13: 51; copy number 14: 12; copy number 15: 99; copy number 16: 96; copy number 17: 296; copy number 18: 274; copy number 19: 21; copy number 20: 19; copy number 21: 107; copy number 24: 41; copy number 26: 45; copy number 30: 31; copy number 31: 96; copy number 37: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-7031-01A-11D-1943-01): tumor purity 0.49, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,259,372, 4 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,609 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:146,145,156–146,145,217, 1 gene, copy number 9: RNU7-2P.
- chr2:157,526,767–158,236,169, 12 genes, copy number 11 (within-gene range 6–11): ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1.
- chr2:159,932,006–167,941,180, 82 genes, copy number 12–16 (broad region; genes not listed).
- chr2:169,645,425–171,231,314, 30 genes, copy number 10 (within-gene range 8–10): CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1.
- chr2:175,842,887–177,392,697, 55 genes, copy number 16 (within-gene range 8–16): EXTL2P1, AC016751.2, AC016751.1, LNPK, EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5.
- chr2:180,571,712–184,939,492, 51 genes, copy number 11–21 (within-gene range 10–21): AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33.
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr5:147,390,808–149,432,835, 46 genes, copy number 9 (within-gene range 4–9): DPYSL3, AC011373.1, JAKMIP2-AS1, JAKMIP2, AC011370.1, SPINK1, AC011352.2, SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN.
- chr8:72,618,722–72,751,843, 3 genes, copy number 12 (within-gene range 8–12): HAUS1P3, AC013562.2, AC013562.1.
- chr8:75,407,914–100,831,860, 395 genes, copy number 9–30 (within-gene range 6–30) (broad region; genes not listed).
- chr8:118,620,498–119,673,453, 17 genes, copy number 31 (within-gene range 3–31): SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr8:123,157,729–145,066,685, 425 genes, copy number 15–37 (within-gene range 3–37) (broad region; genes not listed).
- chr10:123,560,326–123,562,213, 1 gene, copy number 9: AL357127.2.
- chr15:22,838,644–23,407,335, 19 genes, copy number 20: NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3.
- chr15:55,056,723–57,299,281, 45 genes, copy number 13–26 (within-gene range 4–26): AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1, AC010999.2, AC010999.1, TCF12.
- chr15:57,553,955–57,782,762, 6 genes, copy number 11: AC025271.4, AC025271.1, MYZAP, GCOM1, POLR2M, AC090651.1.
- chr15:57,979,716–58,071,043, 3 genes, copy number 11: AC012653.1, AC012653.2, AC025431.1.
- chr16:66,878,589–66,975,149, 8 genes, copy number 9 (within-gene range 3–9): PDP2, CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3.
- chr20:62,804,835–64,313,132, 93 genes, copy number 11 (broad region; genes not listed).
- chr22:18,110,331–18,146,554, 1 gene, copy number 9 (within-gene range 2–9): TUBA8.
- chr22:18,150,170–19,122,454, 49 genes, copy number 9 (within-gene range 2–9): USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, FAM246B, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:21,268,161–26,780,893, 336 genes, copy number 12 (broad region; genes not listed).
- chr22:26,886,909–26,887,548, 1 gene, copy number 12: Z97353.1.
- chr22:30,902,219–30,968,774, 3 genes, copy number 9 (within-gene range 4–9): EIF4HP2, MORC2-AS1, MORC2.
- chr22:35,372,174–39,689,735, 186 genes, copy number 11–18 (within-gene range 6–18) (broad region; genes not listed).
- chr22:50,343,304–50,801,309, 31 genes, copy number 13: PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 388. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
